Gene-level copy-number profile of tumor specimen TCGA-43-3394-01A from TCGA case TCGA-43-3394, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.9 years (19,310 days).
Specimen TCGA-43-3394-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3739ca5f-d410-44bd-b0e7-d64e72ab650a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-3394-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1da63299-c63b-46a6-95b6-b9853a3ca27f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 579; copy number 2: 25,159; copy number 3: 14,599; copy number 4: 8,772; copy number 5: 5,475; copy number 6: 2,926; copy number 7: 455; copy number 8: 481; copy number 9: 57; copy number 10: 929; copy number 11: 121; copy number 12: 60; copy number 13: 1; copy number 15: 96; copy number 16: 78; copy number 23: 6; copy number 24: 1; copy number 34: 8; copy number 37: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-3394-01A-01D-1549-01): tumor purity 0.6, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,666 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–167,518,610, 957 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr2:38,814–63,046,487, 1,012 genes, copy number 5–15 (within-gene range 4–15) (broad region; genes not listed).
- chr2:176,092,721–179,050,086, 88 genes, copy number 7 (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,798 genes, copy number 6–37 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–8 (broad region; genes not listed).
- chr6:63,193,072–66,728,904, 29 genes, copy number 9–15: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P.
- chr7:70,972–57,837,046, 1,078 genes, copy number 5–6 (broad region; genes not listed).
- chr7:86,643,914–159,233,377, 1,462 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:66,767–43,789,543, 934 genes, copy number 10–11 (broad region; genes not listed).
- chr13:24,680,408–34,928,076, 192 genes, copy number 5 (broad region; genes not listed).
- chr13:53,099,397–64,076,044, 91 genes, copy number 5–10 (broad region; genes not listed).
- chr15:60,479,152–74,873,365, 358 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:80,344,853–101,933,350, 532 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:18,781,111–21,315,232, 151 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:27,638,483–40,629,818, 489 genes, copy number 6–11 (within-gene range 2–11) (broad region; genes not listed).
- chr21:15,614,283–20,356,896, 63 genes, copy number 5 (broad region; genes not listed).
- chr22:27,978,014–28,679,865, 1 gene, copy number 5 (within-gene range 3–5): TTC28.
- chr22:28,232,756–50,801,309, 721 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 579. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
